MMRF case MMRF_1939 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1e80f582-1dcf-4a45-b1a2-0b6ab324a1a3

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 328 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.3 years (24,959 days); ISS stage: III; Days to last known disease status: 328 days; Days to last follow up: 328 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 295 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 328.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 33.5 mg/dL; Immunoglobulin G 74.7 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 8.55 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 27 g/L; Total Protein 12.6 g/dL; Glucose 5.12 mmol/L.
- Day 73 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 21.9 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 5.86 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 7.4 g/dL; Glucose 10.8 mmol/L.
- Day 178 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.87 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 8.1 g/dL; Glucose 6.11 mmol/L.
- Day 262 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 6.44 mmol/L.

Other clinical attributes
- Day -9: Weight: 106 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1939_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1939_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
